Somatic mutation profile of tumor specimen TCGA-A4-A48D-01A (aliquot TCGA-A4-A48D-01A-11D-A25F-10) from TCGA case TCGA-A4-A48D, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 85.0 years (31,038 days).
Specimen TCGA-A4-A48D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3dcac80-b1e8-44a0-9c0c-e1573d674e65.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-A48D-10A (Blood Derived Normal), aliquot TCGA-A4-A48D-10A-01D-A25F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f02f56d-3e32-4bcf-8439-a875c57a7fa7

The open-access MAF lists 117 somatic variants for this specimen: 85 protein-altering or splice-affecting, 27 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 27, Frame Shift Del 11, Splice Region 4, 3'UTR 4, Splice Site 3, In Frame Del 3, Nonsense Mutation 3, Frame Shift Ins 3, Intron 1, In Frame Ins 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM6A | c.1577G>A p.G526E | Missense Mutation (SNP) | VAF 16/26 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV65036851, COSV65039652; called by muse, mutect2
- ACSM2B | c.994C>T p.Q332* | Nonsense Mutation (SNP) | VAF 37/135 reads (27%) | catalogued as COSV61657470; called by muse, mutect2, varscan2
- ADCY10 | c.2098G>A p.V700I | Missense Mutation (SNP) | VAF 81/262 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs759888218, COSV63239987, COSV63244154; called by muse, mutect2, varscan2
- ANK3 | c.11113T>G p.S3705A | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1395242519, COSV55053271; called by muse, mutect2, varscan2
- APOB | c.11873A>G p.Y3958C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777208936, COSV51931762; called by muse, mutect2, varscan2
- ATF7IP | c.626C>G p.P209R | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.165); catalogued as COSV53769069; called by muse, mutect2
- BAZ2B | c.4354G>A p.E1452K | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as COSV58598706; called by muse, mutect2, varscan2
- BMPR1A | c.1342+1G>A p.X448_splice | Splice Site (SNP) | VAF 39/139 reads (28%) | catalogued as rs766986283, COSV64405658; called by muse, mutect2, varscan2
- CA1 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.648); catalogued as COSV56278217; called by muse, mutect2
- CDHR5 | c.721A>G p.T241A | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV62762744; called by muse, mutect2, varscan2
- CHI3L1 | c.487A>G p.K163E | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.04); catalogued as COSV55137748; called by muse, mutect2, varscan2
- CLOCK | c.2375T>C p.L792P | Missense Mutation (SNP) | VAF 51/181 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV59401321; called by muse, varscan2
- DECR1 | c.215_216insA p.K73* | Frame Shift Ins (INS) | VAF 33/119 reads (28%) | catalogued as COSV99616673; called by mutect2, pindel, varscan2
- DEFB136 | c.113C>T p.A38V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV66363835; called by muse, mutect2, varscan2
- DIAPH3 | c.343A>G p.K115E | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.492); catalogued as rs1012752656, COSV57368509; called by muse, mutect2, varscan2
- FLNB | c.7313A>G p.Y2438C | Missense Mutation (SNP) | VAF 7/202 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55876474; called by muse, mutect2
- GAPDHS | c.246-2A>C p.X82_splice | Splice Site (SNP) | VAF 33/138 reads (24%) | catalogued as COSV55882379; called by muse, mutect2, varscan2
- H6PD | c.2266A>G p.T756A | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.089); catalogued as COSV66230820; called by muse, mutect2, varscan2
- HNF4G | c.347A>G p.Q116R (on ENST00000354370 / NM_001330561.2; = p.Q163R on NM_004133.5) | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV62967216; called by muse, mutect2, varscan2
- HUS1B | c.610T>A p.F204I | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV57863898; called by muse, mutect2, varscan2
- ITPR1 | c.8165A>C p.Q2722P (on ENST00000354582; = p.Q2667P on NM_002222.7) | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56977369; called by muse, mutect2, varscan2
- KCNT2 | c.3032G>A p.R1011Q | Missense Mutation (SNP) | VAF 8/164 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1388663440, COSV54074433; called by muse, mutect2
- KDM6A | c.1576G>T p.G526W | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65038047, COSV65048557; called by muse, mutect2, varscan2
- LRRK2 | c.4920A>T p.K1640N | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as rs771487603, COSV54149951; called by muse, mutect2, varscan2
- LRRK2 | c.6399T>A p.N2133K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.345); catalogued as COSV54149969; called by muse, mutect2, varscan2
- MAST4 | c.3557C>A p.A1186E (on ENST00000403625 / NM_001164664.2; = p.A997E on NM_015183.3) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55121927; called by muse, mutect2, varscan2
- MICALL2 | c.2099A>C p.K700T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as COSV52515270; called by muse, mutect2, varscan2
- MIEN1 | c.130A>G p.S44G | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV54068073; called by muse, mutect2, varscan2
- MME | c.723T>A p.A241= | Splice Region (SNP) | VAF 66/144 reads (46%) | catalogued as COSV64706866; called by muse, mutect2, varscan2
- MRTFA | c.461T>C p.L154P | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62932682; called by mutect2, varscan2
- MYBL2 | c.163A>G p.K55E | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV53829088; called by muse, mutect2, varscan2
- MYO1F | c.3G>C p.M1? | Translation Start Site (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV54353704; called by muse, mutect2, varscan2
- NEXN | c.991G>C p.E331Q | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV57356507; called by muse, mutect2, varscan2
- NRDE2 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV62962825; called by muse, mutect2, varscan2
- NRG3 | c.359C>G p.S120C | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs776495833, COSV64555908; called by muse, mutect2, varscan2
- NUBP2 | c.358G>T p.D120Y | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs533118487, COSV51905429; called by muse, mutect2, varscan2
- NUDT13 | c.580T>G p.Y194D | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV61968555, COSV61968607; called by muse, mutect2, varscan2
- NUP210 | c.2157C>T p.V719= | Splice Region (SNP) | VAF 23/188 reads (12%) | catalogued as COSV54405090; called by muse, mutect2, varscan2
- OR52D1 | c.260T>C p.I87T | Missense Mutation (SNP) | VAF 107/394 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59487312; called by muse, mutect2, varscan2
- PCARE | c.1465C>T p.P489S | Missense Mutation (SNP) | VAF 75/234 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV59054308; called by muse, mutect2, varscan2
- PODN | c.247G>T p.G83C (on ENST00000395871; = p.G35C on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.306); catalogued as COSV57012628; called by muse, mutect2, varscan2
- PPP1R3A | c.1585A>G p.K529E | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT tolerated (0.51); PolyPhen benign (0.13); catalogued as COSV52880478; called by muse, mutect2, varscan2
- PTPRN2 | c.2739C>G p.D913E | Missense Mutation (SNP) | VAF 7/90 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.097); catalogued as COSV66104729; called by muse, mutect2
- RGS22 | c.875G>C p.R292T | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.051); catalogued as COSV62660408; called by muse, mutect2, varscan2
- RHAG | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 29/116 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1446598944, COSV57703870; called by muse, mutect2, varscan2
- ROPN1 | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.282); catalogued as COSV51739604; called by muse, mutect2, varscan2
- SCARA3 | c.397C>T p.Q133* | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | catalogued as COSV57269938; called by muse, mutect2
- SCN10A | c.3713T>G p.L1238R | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.262); catalogued as COSV71860978; called by muse, mutect2, varscan2
- SCP2 | c.232C>T p.H78Y | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); catalogued as COSV65260927; called by muse, mutect2, varscan2
- SGSM3 | c.880C>T p.L294F | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV50651776; called by muse, mutect2
- SIK3 | c.1724T>C p.V575A (on ENST00000445177 / NM_001366686.2; = p.V581A on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs747840385, COSV52612587; called by muse, mutect2, varscan2
- SLC16A4 | c.989G>T p.G330V | Missense Mutation (SNP) | VAF 44/142 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV63916372; called by muse, mutect2, varscan2
- SLC6A17 | c.928G>A p.G310S | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1468637919, COSV58992406; called by muse, mutect2, varscan2
- SLC7A6OS | c.510G>C p.E170D | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as COSV50449993; called by muse, mutect2, varscan2
- SMCHD1 | c.1712A>C p.D571A | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55255267; called by muse, mutect2, varscan2
- SMCR8 | c.2783A>T p.D928V | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); catalogued as COSV57398550; called by muse, mutect2, varscan2
- SMG1 | c.5294A>G p.D1765G | Missense Mutation (SNP) | VAF 93/279 reads (33%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.984); catalogued as COSV67170704; called by muse, mutect2, varscan2
- SNX9 | c.831T>G p.T277= | Splice Region (SNP) | VAF 24/98 reads (24%) | catalogued as COSV67583890; called by muse, mutect2, varscan2
- THBS1 | c.3324C>A p.Y1108* | Nonsense Mutation (SNP) | VAF 43/176 reads (24%) | catalogued as COSV52951321; called by muse, mutect2, varscan2
- TIGD4 | c.974G>A p.S325N | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV58549392; called by muse, mutect2, varscan2
- TMEM156 | c.752A>T p.K251I | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.515); catalogued as COSV67929419; called by muse, mutect2, varscan2
- USP12 | c.694T>A p.Y232N | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as COSV56655647; called by muse, mutect2, varscan2
- VCAN | c.1017C>G p.S339R | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54102897; called by muse, mutect2, varscan2
- VWA7 | c.1604A>G p.D535G | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV65173001; called by muse, mutect2, varscan2
- ZNF572 | c.209A>C p.E70A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as COSV60001684; called by muse, mutect2, varscan2
- ZNF687 | c.2252T>G p.L751R | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55016661; called by muse, mutect2, varscan2
- BRD8 | c.248del p.G83Vfs*18 | Frame Shift Del (DEL) | VAF 17/119 reads (14%) | called by mutect2, pindel, varscan2
- CLK3 | c.615_619del p.Y205* (on ENST00000395066 / NM_001130028.1; = p.Y57* on NM_003992.4) | Frame Shift Del (DEL) | VAF 39/163 reads (24%) | called by mutect2, pindel, varscan2
- CYP3A43 | c.138del p.L47Wfs*43 | Frame Shift Del (DEL) | VAF 18/83 reads (22%) | called by mutect2, pindel, varscan2
- DHX9 | c.230_233del p.S77Kfs*8 | Frame Shift Del (DEL) | VAF 5/24 reads (21%) | called by pindel, varscan2
- EXPH5 | c.4293_4297del p.E1432* | Frame Shift Del (DEL) | VAF 27/112 reads (24%) | called by mutect2, pindel, varscan2
- HECW1 | c.3098del p.K1033Sfs*30 | Frame Shift Del (DEL) | VAF 29/107 reads (27%) | called by mutect2, pindel, varscan2
- HSPA4L | c.1017_1026del p.I340Efs*8 | Frame Shift Del (DEL) | VAF 27/137 reads (20%) | called by mutect2, pindel, varscan2
- KCNK9 | c.395_400del p.M132_N133del | In Frame Del (DEL) | VAF 28/204 reads (14%) | called by mutect2, pindel, varscan2
- LEUTX | c.275_283del p.K92_G95delinsR | In Frame Del (DEL) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- NIPBL | c.4901_4904del p.I1634Nfs*4 | Frame Shift Del (DEL) | VAF 74/171 reads (43%) | called by mutect2, pindel, varscan2
- PPP3CA | c.260-1_261del p.X87_splice | Splice Site (DEL) | VAF 9/48 reads (19%) | called by mutect2, pindel, varscan2
- RAB11FIP1 | c.2284dup p.S762Kfs*8 | Frame Shift Ins (INS) | VAF 22/122 reads (18%) | called by mutect2, pindel, varscan2
- RIPOR3 | c.2566-5_2566-4delinsG | Splice Region (DEL) | VAF 27/130 reads (21%) | called by pindel, varscan2*
- TIMELESS | c.102_105dup p.K36Rfs*11 | Frame Shift Ins (INS) | VAF 30/137 reads (22%) | called by mutect2, pindel, varscan2
- TMEM132B | c.2813_2815dup p.N938dup | In Frame Ins (INS) | VAF 25/153 reads (16%) | called by mutect2, pindel, varscan2
- TXNDC15 | c.405_410del p.G137_A138del | In Frame Del (DEL) | VAF 29/174 reads (17%) | called by mutect2, pindel, varscan2
- USP5 | c.2448_2449del p.C816Wfs*18 (on ENST00000229268 / NM_001098536.2; = p.C793Wfs*18 on NM_003481.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 25/167 reads (15%) | called by pindel, varscan2
- WLS | c.73_76del p.Q25Sfs*9 | Frame Shift Del (DEL) | VAF 30/119 reads (25%) | called by mutect2, pindel, varscan2
- ZNF101 | c.244del p.T82Lfs*10 | Frame Shift Del (DEL) | VAF 34/147 reads (23%) | called by mutect2, pindel, varscan2
- AJUBA | c.1299C>T p.N433= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV52984927; called by muse, mutect2, varscan2
- ANKRD28 | c.657C>T p.I219= | Silent (SNP) | VAF 16/123 reads (13%) | catalogued as COSV67517661; called by muse, mutect2, varscan2
- BAAT | c.714A>G p.V238= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as COSV52288171; called by muse, mutect2, varscan2
- CD164 | c.447G>A p.V149= | Silent (SNP) | VAF 34/159 reads (21%) | catalogued as rs1421099655, COSV51533313; called by muse, mutect2, varscan2
- DCST1 | c.1122G>T p.L374= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV55058394; called by muse, mutect2, varscan2
- FASTKD3 | c.351T>C p.S117= | Silent (SNP) | VAF 54/123 reads (44%) | catalogued as COSV52942830; called by muse, mutect2, varscan2
- GPR182 | c.798C>G p.V266= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as COSV55625963; called by muse, mutect2, varscan2
- HIBADH | c.588G>C p.V196= | Silent (SNP) | VAF 32/129 reads (25%) | catalogued as COSV55313221; called by muse, mutect2, varscan2
- HMOX2 | c.375G>T p.V125= | Silent (SNP) | VAF 37/235 reads (16%) | catalogued as COSV54859930; called by muse, mutect2, varscan2
- IFT88 | c.225T>C p.A75= (on ENST00000319980 / NM_001318493.2; = p.A66= on NM_006531.5 and 9 other RefSeq transcripts) | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV60672630; called by muse, mutect2, varscan2
- KRT79 | c.642G>T p.G214= | Silent (SNP) | VAF 26/107 reads (24%) | catalogued as COSV57939480; called by muse, mutect2, varscan2
- LRP2 | c.12093C>A p.V4031= | Silent (SNP) | VAF 36/161 reads (22%) | catalogued as COSV55549323; called by muse, mutect2, varscan2
- MAST4 | c.3558A>T p.A1186= (on ENST00000403625 / NM_001164664.2; = p.A997= on NM_015183.3) | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV55121975; called by muse, varscan2
- MRTFA | c.462C>T p.L154= | Silent (SNP) | VAF 25/106 reads (24%) | catalogued as COSV62932676; called by mutect2, varscan2
- MYO9A | c.3936T>C p.P1312= | Silent (SNP) | VAF 38/115 reads (33%) | catalogued as COSV61849722; called by muse, mutect2, varscan2
- PYCR2 | c.957G>A p.K319= | Silent (SNP) | VAF 7/43 reads (16%) | catalogued as rs1260988194; called by muse, mutect2
- RHOT2 | c.975G>T p.S325= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs967431093, COSV99554377; called by muse, mutect2
- SERPINB6 | c.948G>T p.L316= (on ENST00000612421 / NM_001271823.2; = p.L297= on NM_004568.6) | Silent (SNP) | VAF 45/188 reads (24%) | catalogued as COSV59565518; called by muse, mutect2, varscan2
- SGSM3 | c.241C>T p.L81= | Silent (SNP) | VAF 22/86 reads (26%) | catalogued as COSV50651757, COSV50654079; called by muse, varscan2
- SH3BP5 | c.1039C>T p.L347= | Silent (SNP) | VAF 43/207 reads (21%) | catalogued as COSV53743768; called by muse, mutect2, varscan2
- SLC22A13 | c.591T>C p.A197= | Silent (SNP) | VAF 65/171 reads (38%) | catalogued as COSV61290797; called by muse, mutect2, varscan2
- TBC1D9 | c.1351C>T p.L451= | Silent (SNP) | VAF 8/236 reads (3%) | catalogued as COSV71307266; called by muse, mutect2
- TMEM74B | c.615C>T p.Y205= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as COSV67891855; called by muse, mutect2, varscan2
- VCAN | c.1018A>C p.R340= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV54102907; called by muse, mutect2, varscan2
- VIPR1 | c.1230C>T p.G410= | Silent (SNP) | VAF 52/115 reads (45%) | catalogued as rs764229395, COSV57297116; called by muse, mutect2, varscan2
- ZAN | c.783C>T p.L261= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV61807815; called by muse, mutect2, varscan2
- ZNF251 | c.1995T>A p.I665= | Silent (SNP) | VAF 27/86 reads (31%) | catalogued as COSV52956938; called by muse, mutect2, varscan2
- ARHGEF12 | c.*38T>A | 3'UTR (SNP) | VAF 39/160 reads (24%) | catalogued as COSV100755321; called by muse, mutect2
- COL27A1 | c.2368-1949dup | Intron (INS) | VAF 12/62 reads (19%) | called by mutect2, pindel, varscan2
- RBM15B | c.*958G>C | 3'UTR (SNP) | VAF 67/154 reads (44%) | catalogued as COSV100082437; called by muse, mutect2, varscan2
- SLC35A2 | c.*42C>A | 3'UTR (SNP) | VAF 8/143 reads (6%) | catalogued as COSV99504653; called by muse, mutect2
- ZNF345 | c.*101_*103delinsA | 3'UTR (DEL) | VAF 5/47 reads (11%) | called by pindel, varscan2*
